Somatic mutation profile of tumor specimen TCGA-E3-A3DY-01A (aliquot TCGA-E3-A3DY-01A-11D-A20C-08) from TCGA case TCGA-E3-A3DY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.9 years (13,860 days).
Specimen TCGA-E3-A3DY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 886a824d-a9e6-43d7-9778-b24c502f1708.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E3-A3DY-10A (Blood Derived Normal), aliquot TCGA-E3-A3DY-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ca1f6fb-1677-4c0d-809a-15d9d5c05550

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BDP1 | c.6691C>T p.P2231S | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV62428551; called by muse, mutect2, varscan2
- NADSYN1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs199672894, COSV59809709; called by mutect2, varscan2
- NIPBL | c.2605A>G p.K869E | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.378); catalogued as COSV56941021; called by muse, mutect2
- NLGN4Y | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV52968902; called by muse, mutect2
- SOX30 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV53935882; called by muse, mutect2
